Somatic mutation profile of tumor specimen 0E1CWN from CCDI case PBCCTL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,880 days).
Specimen 0E1CWN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c079ff9-90bc-47b6-9fca-16eef351f492.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1CX3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d2299d-295e-4085-b76d-32d3e6a3bd6e

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF11 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 182/672 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs140673049; called by muse, mutect2, varscan2
- C4orf54 | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1218671536; called by muse, mutect2
- CD36 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 70/1151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs568503917; called by muse, mutect2
- L1CAM | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 74/502 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs372200840, COSV62827456; called by muse, mutect2, varscan2
- ARHGAP42 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 110/638 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ATP8B4 | c.3516T>A p.N1172K | Missense Mutation (SNP) | VAF 178/730 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 40/1215 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FXYD2 | c.89_93dup p.I32Afs*2 | Frame Shift Ins (INS) | VAF 67/414 reads (16%) | called by mutect2, varscan2
- KDM7A | c.43G>T p.G15* | Nonsense Mutation (SNP) | VAF 42/305 reads (14%) | called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 24/902 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- AHR | c.-1365T>C | 5'UTR (SNP) | VAF 23/536 reads (4%) | catalogued as rs1027455705; called by muse, mutect2
- ZNF230 | c.142+11G>A | Intron (SNP) | VAF 85/410 reads (21%) | called by muse, mutect2, varscan2
